Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A560, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A560-01A (Primary Tumor).

[page 1 of 2]
---- SURGICAL PATHOLOGY ----

MEDICAL RECORD | SURGICAL PATHOLOGY

PATHOLOGY REPORT

LEFT LOWER POLE RENAL MASS

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:
renal mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:
renal mass

ICD-0-3
carcinoma papillary renal cell 8260/3
Site: kidney, NOS C64.9
two 1/25/12

=====

PATHOLOGY REPORT

GROSS DESCRIPTION:

The specimen consists of an 8.4 gm, 3.2 x 3.0 x 1.9 cm partial nephrectomy specimen displaying a tan-red, smooth lining consistent with renal capsule. The renal resection margin is tan-brown and scabrous. The capsular margin is inked black, and the renal resection margin is inked blue. The specimen is serially sectioned to reveal a 1.8 x 1.8 x 1.3 cm, tan-brown, mahogany, well-circumscribed mass that is less than 0.1 cm from the renal resection margin and grossly extending to the renal capsule. The mass does not grossly extend into the perinephric fat. There is minimal amounts of uninvolved renal parenchyma at the renal resection margin.

Also received in the same container is a 3.5 x 3.0 x 1.2 cm aggregate of tan-yellow, fatty soft tissue. Sectioning reveals a tan-yellow, unremarkable cut surface.

Representative sections are submitted as follows: 1-4- entire partial nephrectomy specimen; 5- fat within the same container. Please note that a representative portion of tumor is taken for tissue bank.

MICROSCOPIC EXAM
FINAL DIAGNOSIS

Kidney, Left lower pole renal mass, partial nephrectomy
- PAPILLARY RENAL CELL CARCINOMA, TYPE II (FUHRMAN NUCLEAR GRADE 2) (Surgical Pathology Cancer Case Summary)

Surgical Pathology Cancer Case Summary (based on AJCC/UICC TNM, 7th edition)

- Procedure: Partial nephrectomy
- Specimen Laterality: Left
- Tumor Site: Lower pole
- Tumor Size: 1.8 CM
- Tumor Focality: Unifocal
- Macroscopic Extent of Tumor: Tumor limited to kidney
- Histologic Type: Papillary renal cell carcinoma
- Sarcomatoid Features: Not identified

[page 2 of 2]
- Tumor Necrosis: Not identified
- Histologic Grade: Fuhrman grade 2
- Microscopic Tumor Extension: Tumor limited to kidney
- Margins: Margins uninvolved by invasive carcinoma
- Lymph-Vascular Invasion: not identified
- Pathologic Staging: pT1a, pNx
- Lymph nodes: No nodes submitted
- Pathologic Findings in Nonneoplastic Kidney:
- chronic inflammation

Comment: Immunohistochemical stains performed on specimen
was notified of the preliminary diagnosis at the end of the
procedure on

PATHOLOGIST

(End of report)

Diagnosis Discrepancy Primary Nodule		☒
Pathologist Initials	BTB	End Reviewed: 11/21/2012

Source: NCI Genomic Data Commons file 968c3895-5ef5-4496-af6e-0e0c475ba769 (TCGA-MH-A560.F4FB70F4-08D1-4BB4-B02F-5553590DD42E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).